Gene-level copy-number profile of tumor specimen MP2PRT-PAUEFP-TMP1-A from MP2PRT case MP2PRT-PAUEFP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,724 days).
Specimen MP2PRT-PAUEFP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2d0a2f4-df60-46ce-b607-ae65c76fba8a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUEFP-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/2c3d5297-22c5-491b-b760-836f20811a3c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 606; copy number 2: 33,093; copy number 3: 23,271; copy number 4: 1,917.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,170,775–89,192,752, 4 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–3): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
